Somatic mutation profile of tumor specimen MMRF_1537_1_BM_CD138pos (aliquot MMRF_1537_1_BM_CD138pos_T1_KBS5U_L06423) from MMRF case MMRF_1537, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.8 years (22,931 days).
Specimen MMRF_1537_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8427d508-1708-4966-a8f4-56030da133c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1537_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1537_1_PB_Whole_C3_KBS5U_L06462; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6102b92-077d-456a-9bcd-edb8b148bbf0

The open-access MAF lists 137 somatic variants for this specimen: 56 protein-altering or splice-affecting, 13 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 39, Intron 13, Silent 13, 5'Flank 9, 5'UTR 5, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 31/116 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS1 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs374668733; called by muse, mutect2, varscan2
- BEST1 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121918290, CM044952; called by muse, varscan2
- CPZ | c.1689G>C p.K563N (on ENST00000360986 / NM_001014447.3; = p.K552N on NM_003652.3) | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781673041; called by muse, mutect2, varscan2
- DSC2 | c.2138C>T p.T713M | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs180863872, COSV51862683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUS2 | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1478089123; called by muse, mutect2, varscan2
- EML2 | c.747T>G p.H249Q | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99840080; called by muse, mutect2, varscan2
- FAT2 | c.6907C>T p.R2303W | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs201714112; called by muse, mutect2, varscan2
- GLRA3 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.206); catalogued as rs758671619; called by muse, mutect2
- IGLV2-23 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as rs371620489; called by muse, varscan2
- KLHL6 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 131/222 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776834054; called by muse, mutect2, varscan2
- KSR2 | c.237G>T p.L79F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV60368392; called by muse, mutect2, varscan2
- NCKAP5 | c.3115G>T p.V1039F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs1476260067; called by muse, mutect2, varscan2
- RGS22 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs767184037, COSV62667240; called by muse, varscan2
- SLC24A5 | c.989G>C p.W330S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as CM141071; called by muse, mutect2, varscan2
- SPDYE4 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 108/197 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs371237439, COSV60905978; called by muse, mutect2, varscan2
- THEMIS | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV64069342; called by muse, mutect2, varscan2
- WDHD1 | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV100864508; called by muse, mutect2, varscan2
- ADGB | c.863G>T p.W288L | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- ANKRD50 | c.2042T>C p.L681S | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASCL3 | c.265T>A p.S89T | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- BRF1 | c.585A>C p.E195D | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- C1orf226 | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CATSPERB | c.2747C>G p.T916S | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CHD7 | c.6532C>A p.P2178T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCC | c.457A>T p.M153L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMT3A | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 77/146 reads (53%) | called by muse, mutect2, varscan2
- DSG1 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTHD1 | c.2135A>C p.K712T (on ENST00000456874; = p.K547T on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- FCER1A | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FHL2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- FILIP1L | c.1943A>G p.D648G (on ENST00000354552 / NM_182909.3; = p.D408G on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGHV3-64 | c.281A>C p.N94T | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- IGHV3-64 | c.163_164insTATAC p.H55Lfs*32 | Frame Shift Ins (INS) | VAF 38/152 reads (25%) | called by pindel, varscan2
- IVD | c.398C>T p.S133F (on ENST00000651168; = p.S130F on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIF2C | c.1218T>A p.N406K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MAP3K10 | c.1984C>T p.R662W | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- MYH4 | c.1933G>T p.G645C | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYORG | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBEAL2 | c.4644+1G>A p.X1548_splice | Splice Site (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- OTOG | c.5701C>A p.P1901T | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDCD2L | c.228C>A p.H76Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PRRC2A | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- RNPC3 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SLC26A6 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SNED1 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TNFRSF1B | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.22); called by muse, mutect2
- TTLL6 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- VCPKMT | c.44G>A p.S15N | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA5A | c.488G>T p.C163F | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- WDR7 | c.1226dup p.T410Nfs*17 | Frame Shift Ins (INS) | VAF 36/165 reads (22%) | called by mutect2, pindel, varscan2
- YLPM1 | c.1232A>T p.Q411L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- YLPM1 | c.2510G>A p.W837* | Nonsense Mutation (SNP) | VAF 48/280 reads (17%) | called by muse, mutect2, varscan2
- ZNF223 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF385B | c.602A>C p.K201T | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF727 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- AL121899.2 | c.2073C>T p.L691= | Silent (SNP) | VAF 68/158 reads (43%) | catalogued as rs568453082; called by muse, mutect2, varscan2
- COL4A5 | c.354T>C p.P118= | Silent (SNP) | VAF 25/37 reads (68%) | called by muse, mutect2, varscan2
- IGHV3-64 | c.153C>T p.S51= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as rs542523265; called by muse, varscan2
- LRRD1 | c.1350A>C p.G450= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- NEURL4 | c.3585C>G p.T1195= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs373146913; called by muse, mutect2, varscan2
- PSME4 | c.573G>A p.E191= | Silent (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- SACM1L | c.1323C>T p.N441= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs769079017, COSV66613025; called by muse, mutect2, varscan2
- SH3BP4 | c.282C>T p.Y94= | Silent (SNP) | VAF 80/155 reads (52%) | catalogued as rs769843704; called by muse, mutect2, varscan2
- SHPRH | c.1494G>A p.Q498= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV51619389; called by muse, mutect2, varscan2
- TANC1 | c.3729C>T p.S1243= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as rs370745760; called by muse, mutect2, varscan2
- ZFP82 | c.96A>G p.R32= | Silent (SNP) | VAF 54/213 reads (25%) | called by muse, mutect2, varscan2
- ZNF407 | c.5826C>T p.V1942= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs756052115; called by muse, mutect2, varscan2
- ZNF521 | c.1368T>G p.L456= | Silent (SNP) | VAF 49/119 reads (41%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.1341+595A>C | Intron (SNP) | VAF 39/140 reads (28%) | called by muse, mutect2, varscan2
- AFAP1L2 | c.*1100G>T | 3'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- ALK | c.3516-325C>G | Intron (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- ARHGAP18 | c.*814A>T | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915812 C>T | 5'Flank (SNP) | VAF 37/112 reads (33%) | catalogued as rs934677097, COSV100388773; called by muse, mutect2, varscan2
- BCL7A | chr12:122020995 C>T | 5'Flank (SNP) | VAF 35/113 reads (31%) | catalogued as COSV55849233, COSV55850852; called by muse, mutect2, varscan2
- BCL7A | chr12:122021401 G>C | 5'Flank (SNP) | VAF 28/82 reads (34%) | catalogued as rs547304687, COSV55852870; called by muse, mutect2, varscan2
- BRF1 | c.545-222G>A | Intron (SNP) | VAF 47/77 reads (61%) | called by muse, mutect2, varscan2
- BRF1 | c.545-356A>G | Intron (SNP) | VAF 84/181 reads (46%) | called by muse, mutect2, varscan2
- C11orf96 | chr11:43943657 G>A | 3'Flank (SNP) | VAF 90/148 reads (61%) | called by muse, mutect2, varscan2
- CAMK2D | c.985-4502T>G | Intron (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2, varscan2
- CASK | c.1156-41G>C | Intron (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- CFAP52 | c.71-1583C>T | Intron (SNP) | VAF 26/48 reads (54%) | called by muse, varscan2
- CNIH4 | c.*3437T>A | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.*909C>T | 3'UTR (SNP) | VAF 19/42 reads (45%) | catalogued as rs1034172267; called by muse, mutect2, varscan2
- CRACR2A | c.*307G>T | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- CSH2 | chr17:63873741 C>A | 5'Flank (SNP) | VAF 46/292 reads (16%) | called by muse, mutect2, varscan2
- CUL5 | c.*2843G>T | 3'UTR (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- DIRAS2 | c.*2657T>G | 3'UTR (SNP) | VAF 62/109 reads (57%) | called by muse, varscan2
- DMAC1 | c.*1114G>A | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- ERICH1 | c.*21G>C | 3'UTR (SNP) | VAF 61/236 reads (26%) | called by muse, mutect2, varscan2
- FLAD1 | c.-42G>A | 5'UTR (SNP) | VAF 25/136 reads (18%) | catalogued as rs1160077110, COSV99422784; called by muse, mutect2, varscan2
- GJB7 | c.*517G>A | 3'UTR (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- GNG7 | c.-38+16415C>T | Intron (SNP) | VAF 48/221 reads (22%) | called by muse, mutect2, varscan2
- GPM6A | c.*679_*680del | 3'UTR (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- HEYL | c.*1792G>T | 3'UTR (SNP) | VAF 39/153 reads (25%) | called by muse, mutect2, varscan2
- HPS1 | c.937+285G>T | Intron (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- HS3ST4 | c.*1002G>C | 3'UTR (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- IGHV3-64 | c.-1C>T | 5'UTR (SNP) | VAF 58/159 reads (36%) | catalogued as rs1334367314; called by muse, mutect2
- IGLC2 | c.*104A>G | 3'UTR (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- JAK2 | c.*309A>G | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- JUP | c.*11C>G | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- KCND2 | c.*2425dup | 3'UTR (INS) | VAF 6/23 reads (26%) | catalogued as rs888166955; called by mutect2, varscan2
- LINC00523 | n.1012G>A | RNA (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- LYST | c.*608A>G | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851218 G>C | 5'Flank (SNP) | VAF 74/177 reads (42%) | catalogued as rs746314598; called by muse, varscan2
- MIR5195 | chr14:106851228 T>C | 5'Flank (SNP) | VAF 66/166 reads (40%) | catalogued as rs563204262; called by muse, varscan2
- MIR5195 | chr14:106851319 T>A | 5'Flank (SNP) | VAF 54/148 reads (36%) | catalogued as rs571766953; called by muse, varscan2
- NDUFAF5 | c.*329C>T | 3'UTR (SNP) | VAF 27/90 reads (30%) | catalogued as rs1300841983; called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21173935 G>A | 5'Flank (SNP) | VAF 11/37 reads (30%) | catalogued as rs1432386195; called by muse, mutect2, varscan2
- NLRP12 | c.-17G>T | 5'UTR (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- OSBPL8 | c.*914G>A | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- PAPOLB | c.*1891G>T | 3'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-9775G>A | Intron (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- PIH1D1 | c.-115G>A | 5'UTR (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*3838G>T | 3'UTR (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- PLXDC2 | chr10:19816185 A>T | 5'Flank (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- POFUT1 | c.*417T>G | 3'UTR (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- PPIP5K2 | c.*488G>C | 3'UTR (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- PTBP2 | c.*241T>G | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- QRSL1 | c.849+971G>A | Intron (SNP) | VAF 36/59 reads (61%) | called by muse, mutect2, varscan2
- RCC1L | c.*638A>T | 3'UTR (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- RGMB | c.*1942G>A | 3'UTR (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- RHOQ | c.*1967A>G | 3'UTR (SNP) | VAF 101/244 reads (41%) | catalogued as rs187512547; called by muse, mutect2, varscan2
- RNF169 | c.*3385G>A | 3'UTR (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- ROBO1 | c.*364T>G | 3'UTR (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- RUNDC3B | c.*1060A>T | 3'UTR (SNP) | VAF 7/25 reads (28%) | catalogued as rs557650154, COSV56690744; called by muse, mutect2, varscan2
- SCFD2 | c.*61C>G | 3'UTR (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- SESN3 | c.*3619C>A | 3'UTR (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- SGPP1 | c.*1030T>A | 3'UTR (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- SGTB | c.*2889A>C | 3'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- SLC23A2 | c.*3020C>T | 3'UTR (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- SNCAIP | c.1423-897G>T | Intron (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.*4064G>T | 3'UTR (SNP) | VAF 37/279 reads (13%) | called by muse, mutect2, varscan2
- STRA6 | c.267-20T>A | Intron (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- TFAP4 | c.*218G>A | 3'UTR (SNP) | VAF 24/53 reads (45%) | catalogued as rs1567199171; called by muse, mutect2, varscan2
- VEGFC | c.-135G>A | 5'UTR (SNP) | VAF 9/38 reads (24%) | catalogued as rs1050663584; called by muse, mutect2
- ZBTB11 | c.*1792_*1796del | 3'UTR (DEL) | VAF 32/102 reads (31%) | catalogued as rs1467971016; called by mutect2, pindel, varscan2
